Gene-level copy-number profile of tumor specimen ALCH-AFA6-TTP1-A from ALCHEMIST case ALCH-AFA6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.4 years (22,444 days).
Specimen ALCH-AFA6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 51940622-69bf-4477-836d-3c790b3d0344.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFA6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/338920ae-8edf-4e0c-ae69-eb674d3904ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 2,671; copy number 2: 53,642; copy number 3: 1,912; copy number 4: 62; copy number 5: 5; copy number 6: 3; copy number 9: 2; copy number 12: 2; copy number 18: 3; copy number 24: 1; copy number 34: 2.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,150,494–110,202,202, 3 genes: SLC6A17, SLC6A17-AS1, AL355990.1.
- chr2:239,734,956–239,824,764, 2 genes: AC093802.2, AC093802.1.
- chr3:50,419,781–50,419,899, 1 gene (within-gene range 0–1): RNA5SP131.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr7:6,952,625–7,104,482, 3 genes (within-gene range 0–2): AC079804.3, MIR3683, AC092104.1.
- chr7:144,397,240–144,410,227, 1 gene: NOBOX.
- chr7:155,458,129–155,464,831, 1 gene: EN2.
- chr8:22,604,632–22,621,514, 2 genes (within-gene range 0–1): CCAR2, AC037459.2.
- chr8:141,353,403–141,355,365, 1 gene: AC100803.3.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr10:3,134,566–3,172,841, 3 genes (within-gene range 0–2): AL451164.2, PITRM1, PITRM1-AS1.
- chr10:86,630,825–86,666,848, 2 genes: RPL7AP8, OPN4.
- chr10:103,608,619–103,610,050, 1 gene (within-gene range 0–2): AL121929.2.
- chr11:818,914–832,883, 3 genes (within-gene range 0–2): PNPLA2, AP006621.1, CRACR2B.
- chr11:842,812–867,116, 2 genes: TSPAN4, AP006623.1.
- chr11:69,004,394–69,018,447, 3 genes: AP003071.3, MRGPRF, MRGPRF-AS1.
- chr12:59,523,278–59,524,184, 1 gene: LINC02448.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr15:25,176,832–25,227,190, 28 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:74,337,759–74,367,646, 2 genes (within-gene range 0–2): CYP11A1, PPIAP46.
- chr15:77,043,680–77,045,160, 1 gene (within-gene range 0–2): AC090181.1.
- chr16:2,090,195–2,090,284, 1 gene (within-gene range 0–2): MIR1225.
- chr16:2,106,669–2,106,753, 1 gene (within-gene range 0–2): MIR6511B1.
- chr16:32,903,442–32,903,894, 1 gene: IGHV3OR16-15.
- chr17:142,789–181,650, 1 gene: DOC2B.
- chr17:81,976,807–82,024,107, 2 genes (within-gene range 0–2): ASPSCR1, CENPX.
- chr19:2,235,829–2,235,926, 1 gene (within-gene range 0–2): MIR6789.
- chr19:10,871,553–10,933,535, 3 genes: CARM1, YIPF2, TIMM29.
- chr20:5,507,875–5,510,002, 1 gene: LINC01729.
- chr20:25,248,085–25,298,012, 3 genes (within-gene range 0–2): PYGB, AL121772.2, AL121772.3.
- chr20:62,804,835–62,814,000, 1 gene (within-gene range 0–1): OGFR.
- chr20:64,073,181–64,079,988, 2 genes: RGS19, MIR6813.
- chr20:64,083,380–64,084,359, 1 gene (within-gene range 0–2): LKAAEAR1.
- chr20:64,105,820–64,107,171, 1 gene: NPBWR2.
- chr21:44,347,767–44,348,295, 1 gene: AP001063.1.
- chr22:19,031,564–19,034,564, 1 gene: CA15P1.
- chr22:19,045,256–19,045,367, 1 gene (within-gene range 0–2): Y_RNA.
- chr22:21,028,718–21,032,840, 1 gene (within-gene range 0–2): SLC7A4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–1,989,920, 2 genes, copy number 12: MRPL23, MRPL23-AS1.
- chr12:6,747,996–6,770,952, 2 genes, copy number 5: MLF2, PTMS.
- chr16:33,533,816–33,570,935, 4 genes, copy number 18–34: AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr17:81,017,969–81,028,079, 2 genes, copy number 5: AC127496.5, AC127496.2.
- chr20:63,639,705–63,657,682, 1 gene, copy number 5: STMN3.
- chr21:43,107,942–43,168,646, 2 genes, copy number 9–18 (within-gene range 4–18): AP001631.2, MRPL51P2.
- chr21:43,159,066–43,172,805, 2 genes, copy number 9–24: AP001631.1, CRYAA.
- chr21:44,217,014–44,244,993, 3 genes, copy number 6: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 2,670. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
